Somatic mutation profile of tumor specimen ALCH-B2WN-TTP1-A (aliquot ALCH-B2WN-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B2WN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.1 years (23,050 days).
Specimen ALCH-B2WN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2649ef38-0219-41fc-b575-910522d2b2d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2WN-NB1-A (Blood Derived Normal), aliquot ALCH-B2WN-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09e4dfa4-6041-4487-840f-d7aeaa57f396

The open-access MAF lists 48 somatic variants for this specimen: 32 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 13, Splice Region 3, Nonsense Mutation 2, Intron 2, 5'UTR 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 161/1073 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 76/745 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs1326236450; called by muse, mutect2, varscan2
- CFAP47 | c.871G>A p.V291M | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as rs149025161, COSV52888096; called by muse, mutect2
- CRY1 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 30/401 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.408); catalogued as rs147813518; called by muse, mutect2
- CYP11B2 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 50/934 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771766541, COSV59994392; called by muse, mutect2
- DMD | c.2098C>A p.Q700K | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as CD067164, CM080211; called by muse, mutect2
- KLHL2 | c.24C>T p.P8= | Splice Region (SNP) | VAF 15/189 reads (8%) | catalogued as rs1350473885; called by muse, mutect2
- NDNF | c.1163A>G p.Q388R | Missense Mutation (SNP) | VAF 50/360 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV101113136; called by muse, mutect2, varscan2
- NLRP14 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 38/710 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.2); catalogued as rs1398246177, COSV55071485; called by muse, mutect2
- OR5H2 | c.126C>G p.I42M | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs141995751, COSV100788659; called by muse, mutect2
- PLK5 | c.489C>T p.A163= | Splice Region (SNP) | VAF 20/186 reads (11%) | catalogued as rs530946143; called by muse, mutect2
- RELN | c.3023G>A p.R1008H | Missense Mutation (SNP) | VAF 50/952 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1390453425, COSV58985444; called by muse, mutect2
- RPL11 | c.296C>G p.S99* (on ENST00000374550 / NM_001199802.1; = p.S100* on NM_000975.5) | Nonsense Mutation (SNP) | VAF 33/632 reads (5%) | catalogued as COSV65778420; called by muse, mutect2
- ACSM6 | c.115A>T p.R39W | Missense Mutation (SNP) | VAF 43/297 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- ANKRD34A | c.1433A>T p.Q478L | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- ATP10B | c.1415C>G p.S472* | Nonsense Mutation (SNP) | VAF 22/250 reads (9%) | called by muse, mutect2
- CCDC91 | c.69-2A>G p.X23_splice | Splice Site (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- CLCN6 | c.1447T>G p.S483A | Missense Mutation (SNP) | VAF 30/402 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.079); called by muse, mutect2
- CLSPN | c.2552C>T p.T851I | Missense Mutation (SNP) | VAF 20/343 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.176); called by muse, mutect2
- EXOC2 | c.1838G>A p.G613E | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HSPA12A | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 24/476 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.31); called by muse, mutect2
- LRRCC1 | c.1012G>A p.G338R | Missense Mutation (SNP) | VAF 47/762 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.701); called by muse, mutect2
- OR4C6 | c.611T>G p.M204R | Missense Mutation (SNP) | VAF 26/482 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- PINLYP | c.480T>C p.A160= | Splice Region (SNP) | VAF 18/151 reads (12%) | called by muse, mutect2, varscan2
- PLEKHG7 | c.1019T>C p.L340P | Missense Mutation (SNP) | VAF 23/314 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.389); called by muse, mutect2
- PRPF6 | c.2681del p.Q894Rfs*4 | Frame Shift Del (DEL) | VAF 76/511 reads (15%) | called by mutect2, pindel, varscan2
- RELN | c.7138A>T p.I2380L | Missense Mutation (SNP) | VAF 33/660 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- RPIA | c.335T>G p.V112G | Missense Mutation (SNP) | VAF 68/1044 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- SCARB1 | c.1337A>T p.Y446F | Missense Mutation (SNP) | VAF 52/688 reads (8%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); called by muse, mutect2
- TECTA | c.269C>G p.T90R | Missense Mutation (SNP) | VAF 31/278 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- USH2A | c.10673A>C p.Q3558P | Missense Mutation (SNP) | VAF 18/498 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.276); called by muse, mutect2
- ZNF764 | c.527G>A p.G176D | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- DDX1 | c.1857G>A p.V619= | Silent (SNP) | VAF 35/602 reads (6%) | catalogued as rs903169352; called by muse, mutect2
- EML1 | c.1842A>G p.E614= | Silent (SNP) | VAF 20/331 reads (6%) | called by muse, mutect2
- GDF10 | c.852G>A p.A284= | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as rs782612950; called by muse, mutect2
- GRK1 | c.126C>G p.P42= | Silent (SNP) | VAF 24/226 reads (11%) | called by muse, varscan2
- GUCY1A2 | c.576A>C p.V192= | Silent (SNP) | VAF 22/340 reads (6%) | called by muse, mutect2
- IGKV2D-24 | c.75C>G p.T25= | Silent (SNP) | VAF 24/245 reads (10%) | called by muse, mutect2
- MC2R | c.234C>A p.I78= | Silent (SNP) | VAF 62/1064 reads (6%) | catalogued as COSV59616997; called by muse, mutect2
- MYH6 | c.2973C>T p.I991= | Silent (SNP) | VAF 44/582 reads (8%) | catalogued as rs374807345; ClinVar: likely benign; called by muse, mutect2
- PCDHA7 | c.1326C>T p.S442= | Silent (SNP) | VAF 40/646 reads (6%) | catalogued as rs782335275; called by muse, mutect2
- RIPOR1 | c.2895G>C p.S965= (on ENST00000379312 / NM_001193522.2; = p.S961= on NM_024519.4) | Silent (SNP) | VAF 18/155 reads (12%) | catalogued as rs1344914288; called by muse, mutect2
- SHMT1 | c.414C>A p.I138= | Silent (SNP) | VAF 20/380 reads (5%) | called by muse, mutect2
- TRPM2 | c.60G>T p.L20= | Silent (SNP) | VAF 17/199 reads (9%) | called by muse, mutect2
- VWF | c.6078G>T p.G2026= | Silent (SNP) | VAF 40/542 reads (7%) | called by muse, mutect2
- AGGF1 | c.-217C>T | 5'UTR (SNP) | VAF 45/346 reads (13%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.12399+17G>T | Intron (SNP) | VAF 103/645 reads (16%) | catalogued as rs1001937252; called by muse, mutect2, varscan2
- NIPBL | c.3122-21A>T | Intron (SNP) | VAF 30/212 reads (14%) | catalogued as rs754450873; called by mutect2, varscan2
